CCDI case PBCJYV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lip.
https://portal.gdc.cancer.gov/cases/30190d2b-2298-4473-ae15-eecc6dcbd80a

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lip, NOS; Age at diagnosis: 6.6 years (2,411 days).

Biospecimens (3 samples)
- Sample 0DTYAK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTYAU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTYB4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
